Somatic mutation profile of tumor specimen TARGET-10-PARDXI-03A (aliquot TARGET-10-PARDXI-03A-01D) from TARGET case TARGET-10-PARDXI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.4 years (3,801 days).
Specimen TARGET-10-PARDXI-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52e92609-7fad-4eee-8653-19aaa318af6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDXI-10A (Blood Derived Normal), aliquot TARGET-10-PARDXI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47a47c92-dcdc-48e7-a924-3ef1c358a65e

The open-access MAF lists 37 somatic variants for this specimen: 21 protein-altering or splice-affecting, 10 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 10, RNA 3, Intron 2, Nonsense Mutation 1, Splice Region 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.857A>C p.E286A | Missense Mutation (SNP) | VAF 10/29 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1057519985, CM920679, COSV52661405, COSV52748431, COSV53044704; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 12/24 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CSMD3 | c.2249C>T p.T750M (on ENST00000297405 / NM_001363185.1; = p.T646M on NM_052900.3) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1490537303, COSV52337134, COSV99820895; called by muse, mutect2, varscan2
- CYP11B2 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs562670189, COSV59995904; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- FMR1NB | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100789525; called by muse, mutect2, varscan2
- FOXP1 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59553946; called by muse, mutect2, varscan2
- GABRA5 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171210102, COSV59477866; called by muse, mutect2, varscan2
- GPR179 | c.2522C>T p.S841L (on ENST00000621958; = p.S840L on NM_001004334.4) | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376149092; called by muse, mutect2, varscan2
- MAST4 | c.5069G>A p.R1690Q (on ENST00000403625 / NM_001164664.2; = p.R1501Q on NM_015183.3) | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs772017807, COSV55128625; called by muse, mutect2, varscan2
- OBSL1 | c.4855G>A p.A1619T | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as rs573656951, COSV54705545; called by muse, mutect2, varscan2
- OR2F2 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs755050627; called by muse, mutect2, varscan2
- SRPX | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.567); catalogued as rs777506032; called by muse, mutect2, varscan2
- ZFHX4 | c.7750G>A p.D2584N | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs774272950, COSV50639548; called by muse, mutect2, varscan2
- ZSCAN20 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs371224785; called by muse, mutect2, varscan2
- ATAD3C | c.692T>A p.L231H | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FBXL12 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- FGD1 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- FNDC7 | c.1146G>T p.L382F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by mutect2, varscan2
- KCNQ1 | c.384C>A p.A128= | Splice Region (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- LRRC8C | c.509G>A p.W170* | Nonsense Mutation (SNP) | VAF 60/133 reads (45%) | called by muse, mutect2, varscan2
- SRCAP | c.8016_8035del p.T2673Gfs*18 | Frame Shift Del (DEL) | VAF 38/90 reads (42%) | called by mutect2, varscan2
- ANKEF1 | c.954C>T p.A318= | Silent (SNP) | VAF 36/86 reads (42%) | called by muse, mutect2, varscan2
- CLDN18 | c.747C>T p.D249= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs370767483; called by muse, mutect2, varscan2
- KLF9 | c.678C>T p.T226= | Silent (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- MRC2 | c.351G>T p.L117= | Silent (SNP) | VAF 34/143 reads (24%) | called by muse, mutect2, varscan2
- MYF6 | c.222C>T p.P74= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs1355789333, COSV57350996, COSV57351164; called by muse, mutect2, varscan2
- RBMXL3 | c.2319C>T p.Y773= | Silent (SNP) | VAF 62/124 reads (50%) | catalogued as rs782044389; called by muse, mutect2, varscan2
- RPE65 | c.1194C>T p.D398= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as rs139640666, COSV52019104; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SLCO6A1 | c.126G>A p.S42= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV65805483; called by muse, mutect2, varscan2
- SLIT2 | c.3411C>T p.I1137= | Silent (SNP) | VAF 74/124 reads (60%) | catalogued as rs1259582147, COSV56567457; called by muse, mutect2, varscan2
- ZBED1 | c.936G>T p.L312= | Silent (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- CACNA1A | c.5547-1266G>C | Intron (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- FRG1GP | n.691A>T | RNA (SNP) | VAF 34/189 reads (18%) | catalogued as rs1246148236; called by muse, mutect2, varscan2
- FUNDC2P2 | n.118G>A | RNA (SNP) | VAF 25/58 reads (43%) | catalogued as rs747169228; called by muse, mutect2, varscan2
- MIR323B | n.60C>T | RNA (SNP) | VAF 14/60 reads (23%) | catalogued as rs757275040; called by muse, mutect2, varscan2
- PRKRA | c.785-113A>T | Intron (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- ZNF540 | c.-51C>T | 5'UTR (SNP) | VAF 27/67 reads (40%) | called by muse, mutect2, varscan2
